Somatic mutation profile of tumor specimen C3L-06339-01 (aliquot CPT0362880009) from CPTAC case C3L-06339, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 60.4 years (22,077 days).
Specimen C3L-06339-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe27af00-d5a7-422d-9c63-fc43e5e92454.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06339-31 (Blood Derived Normal), aliquot CPT0362940002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6b6ee8d-1fce-450a-90b6-c2be9678e537

The open-access MAF lists 108 somatic variants for this specimen: 67 protein-altering or splice-affecting, 38 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 38, Nonsense Mutation 5, Intron 2, Frame Shift Del 1, Frame Shift Ins 1, Splice Region 1, Translation Start Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 109/333 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- TTN | c.51869G>A p.W17290* (on ENST00000591111; = p.W9866* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 73/498 reads (15%) | catalogued as rs1060500526, COSV100620498; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRG4 | c.7354C>T p.P2452S | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV54956055; called by muse, mutect2, varscan2
- ADGRV1 | c.15407C>T p.S5136F | Missense Mutation (SNP) | VAF 150/407 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as rs867467575, COSV67987841, COSV67994326; called by muse, mutect2, varscan2
- BBC3 | c.649C>T p.Q217* (on ENST00000449228 / NM_001127240.3; = p.P182= on NM_014417.5) | Nonsense Mutation (SNP) | VAF 215/618 reads (35%) | catalogued as COSV100340842, COSV100340899; called by muse, mutect2, varscan2
- CARD11 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 151/672 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62716832; called by muse, mutect2, varscan2
- CCL17 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 83/251 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.922); catalogued as rs567664586; called by muse, mutect2, varscan2
- COL12A1 | c.5746G>A p.V1916I | Missense Mutation (SNP) | VAF 76/311 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.506); catalogued as rs778672810, COSV59398244; called by muse, mutect2, varscan2
- DEUP1 | c.432G>A p.E144= | Splice Region (SNP) | VAF 29/114 reads (25%) | catalogued as COSV99976688; called by muse, mutect2, varscan2
- DOCK6 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 94/544 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.157); catalogued as rs764829646; called by muse, mutect2, varscan2
- DPP3 | c.1904C>T p.A635V | Missense Mutation (SNP) | VAF 85/348 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs764423422; called by muse, mutect2, varscan2
- FAT4 | c.5443C>T p.R1815C | Missense Mutation (SNP) | VAF 87/370 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766427266, COSV58670665; called by muse, mutect2, varscan2
- FCAR | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 62/355 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV62029544; called by muse, mutect2, varscan2
- FGD5 | c.3016G>A p.E1006K | Missense Mutation (SNP) | VAF 61/316 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV99549092; called by muse, mutect2, varscan2
- HEPACAM | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 56/270 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); catalogued as COSV100005924; called by muse, mutect2, varscan2
- IDO1 | c.401G>T p.W134L | Missense Mutation (SNP) | VAF 43/228 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53715551; called by mutect2, varscan2
- IGHG2 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 79/749 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs587630560; called by muse, mutect2, varscan2
- ISX | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 88/334 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372031013; called by muse, mutect2, varscan2
- KRCC1 | c.217A>T p.R73* | Nonsense Mutation (SNP) | VAF 36/516 reads (7%) | catalogued as rs1273416827; called by muse, mutect2
- KRT37 | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 129/369 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); catalogued as rs1555556260; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1091C>T p.S364L | Missense Mutation (SNP) | VAF 254/703 reads (36%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.167); catalogued as rs538471138; called by muse, mutect2, varscan2
- MBOAT4 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 102/442 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs146255946, COSV57642281; called by muse, mutect2, varscan2
- NCOR2 | c.2923C>T p.P975S | Missense Mutation (SNP) | VAF 86/276 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1265081325; called by mutect2, varscan2
- NLGN1 | c.1736C>T p.S579F | Missense Mutation (SNP) | VAF 46/266 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as rs970254907; called by muse, mutect2, varscan2
- OOSP2 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 49/215 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140171460, COSV53928347, COSV99613480; called by muse, mutect2, varscan2
- PAQR6 | c.103G>T p.A35S | Missense Mutation (SNP) | VAF 103/577 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV52744272; called by muse, mutect2, varscan2
- PARD3B | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 54/291 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs754881391; called by muse, mutect2, varscan2
- PLCB1 | c.2159G>A p.G720E | Missense Mutation (SNP) | VAF 109/321 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV62039711; called by muse, mutect2, varscan2
- SENP5 | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 90/412 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.037); catalogued as COSV60208705; called by muse, mutect2, varscan2
- SLC22A24 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 44/237 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs765593659, COSV58223786; called by muse, mutect2, varscan2
- SLC25A2 | c.594dup p.A199Cfs*8 | Frame Shift Ins (INS) | VAF 55/362 reads (15%) | catalogued as rs782317701; called by mutect2, pindel, varscan2
- SLIT2 | c.3781C>A p.P1261T | Missense Mutation (SNP) | VAF 97/388 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56564844; called by muse, mutect2, varscan2
- TCP10L2 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 81/430 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs766414211; called by muse, mutect2, varscan2
- ZNF569 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 89/255 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV57594390, COSV57595024; called by muse, mutect2, varscan2
- APBB1IP | c.1728G>A p.M576I | Missense Mutation (SNP) | VAF 146/482 reads (30%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, varscan2
- BACH2 | c.2137G>C p.V713L | Missense Mutation (SNP) | VAF 72/254 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- DUS2 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 59/426 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- GLI3 | c.608A>T p.Y203F | Missense Mutation (SNP) | VAF 215/688 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- GLT1D1 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 92/336 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- GLYATL1 | c.708A>C p.E236D (on ENST00000317391 / NM_001354699.1; = p.E267D on NM_080661.4) | Missense Mutation (SNP) | VAF 92/380 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.097); called by mutect2, varscan2
- HMGXB3 | c.3652G>T p.E1218* (on ENST00000613459; = p.E972* on NM_014983.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 147/407 reads (36%) | called by muse, mutect2, varscan2
- IGDCC4 | c.3037C>G p.P1013A | Missense Mutation (SNP) | VAF 114/441 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- IGHV3-35 | c.50T>G p.V17G | Missense Mutation (SNP) | VAF 92/566 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- KCTD4 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 63/285 reads (22%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MALRD1 | c.2697G>A p.M899I | Missense Mutation (SNP) | VAF 132/577 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- OCM2 | c.82C>A p.Q28K | Missense Mutation (SNP) | VAF 178/472 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PARD3B | c.1430A>C p.E477A | Missense Mutation (SNP) | VAF 48/268 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- PDE3A | c.1487C>T p.S496F | Missense Mutation (SNP) | VAF 70/290 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- PPA2 | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 36/189 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP2R3A | c.3197_3207del p.Q1066Lfs*8 | Frame Shift Del (DEL) | VAF 30/246 reads (12%) | called by mutect2, pindel
- RAB11FIP2 | c.1387C>T p.H463Y | Missense Mutation (SNP) | VAF 143/326 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- SLC25A23 | c.676C>T p.L226F | Missense Mutation (SNP) | VAF 66/427 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- SMG5 | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 262/576 reads (45%) | called by muse, mutect2, varscan2
- SON | c.5366A>G p.D1789G | Missense Mutation (SNP) | VAF 49/302 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SVEP1 | c.2806T>C p.W936R | Missense Mutation (SNP) | VAF 142/307 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- TOPORS | c.2887G>C p.D963H | Missense Mutation (SNP) | VAF 77/497 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.173); called by muse, mutect2
- TOPORS | c.2294A>C p.E765A | Missense Mutation (SNP) | VAF 54/416 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.297); called by muse, varscan2
- TOPORS | c.2162G>C p.R721T | Missense Mutation (SNP) | VAF 46/366 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); called by muse, varscan2
- TOPORS | c.2042G>C p.R681T | Missense Mutation (SNP) | VAF 57/448 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- TRAV27 | c.73A>C p.S25R | Missense Mutation (SNP) | VAF 28/234 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- TRPC4 | c.652C>G p.L218V | Missense Mutation (SNP) | VAF 20/439 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- UGT2B11 | c.692A>C p.K231T | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.038); called by muse, mutect2
- ZNF469 | c.8180T>G p.F2727C (on ENST00000437464; = p.F2755C on NM_001367624.2) | Missense Mutation (SNP) | VAF 234/619 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF701 | c.1325A>G p.H442R (on ENST00000301093; = p.H376R on NM_018260.3) | Missense Mutation (SNP) | VAF 152/469 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZNF729 | c.1618G>A p.G540R | Missense Mutation (SNP) | VAF 100/337 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- ZNF776 | c.1528C>T p.H510Y | Missense Mutation (SNP) | VAF 78/286 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- ZP2 | c.648G>A p.M216I | Missense Mutation (SNP) | VAF 85/398 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABHD16A | c.1206C>T p.T402= | Silent (SNP) | VAF 89/494 reads (18%) | catalogued as rs570037754, COSV65451682; called by muse, mutect2, varscan2
- ACTRT2 | c.1041C>T p.I347= | Silent (SNP) | VAF 106/464 reads (23%) | catalogued as rs918745739; called by muse, mutect2, varscan2
- ANAPC5 | c.2139C>T p.V713= | Silent (SNP) | VAF 88/416 reads (21%) | catalogued as rs1425112210; called by muse, mutect2, varscan2
- AOC3 | c.1578C>T p.F526= | Silent (SNP) | VAF 109/345 reads (32%) | catalogued as COSV53829451; called by muse, mutect2, varscan2
- ARPP21 | c.1269C>T p.S423= | Silent (SNP) | VAF 62/363 reads (17%) | called by muse, mutect2, varscan2
- ATG2A | c.876G>A p.R292= | Silent (SNP) | VAF 14/279 reads (5%) | called by muse, mutect2
- CATSPER2 | c.1452G>A p.Q484= (on ENST00000321596 / NM_001282309.3; = p.Q486= on NM_172095.4) | Silent (SNP) | VAF 84/579 reads (15%) | called by muse, mutect2, varscan2
- CDCA4 | c.543C>T p.F181= | Silent (SNP) | VAF 223/568 reads (39%) | catalogued as rs773387485; called by muse, mutect2, varscan2
- CFHR5 | c.1086C>T p.I362= | Silent (SNP) | VAF 62/306 reads (20%) | called by muse, mutect2, varscan2
- DISC1 | c.2106C>T p.I702= | Silent (SNP) | VAF 91/551 reads (17%) | catalogued as rs2806455; called by muse, mutect2, varscan2
- DNAH6 | c.8568G>A p.K2856= | Silent (SNP) | VAF 57/299 reads (19%) | called by muse, mutect2, varscan2
- DNAJA1 | c.777C>T p.F259= | Silent (SNP) | VAF 32/268 reads (12%) | catalogued as rs746496251; called by muse, mutect2, varscan2
- DOCK2 | c.1773G>A p.G591= | Silent (SNP) | VAF 193/527 reads (37%) | called by muse, mutect2, varscan2
- DUS2 | c.288C>T p.A96= | Silent (SNP) | VAF 61/432 reads (14%) | called by muse, mutect2, varscan2
- DZIP1 | c.333G>C p.S111= | Silent (SNP) | VAF 120/495 reads (24%) | called by muse, mutect2, varscan2
- ERCC1 | c.666C>T p.L222= | Silent (SNP) | VAF 95/318 reads (30%) | called by muse, mutect2, varscan2
- ERCC2 | c.696C>T p.V232= | Silent (SNP) | VAF 92/421 reads (22%) | called by muse, mutect2, varscan2
- FASTK | c.525C>G p.P175= | Silent (SNP) | VAF 188/502 reads (37%) | called by muse, mutect2, varscan2
- FER1L6 | c.3495G>A p.P1165= | Silent (SNP) | VAF 72/526 reads (14%) | catalogued as rs1240731183, COSV101205642, COSV67549084; called by muse, mutect2, varscan2
- GPHB5 | c.129C>T p.F43= | Silent (SNP) | VAF 99/417 reads (24%) | catalogued as COSV58486060; called by muse, mutect2, varscan2
- GRM3 | c.1182G>A p.V394= | Silent (SNP) | VAF 176/670 reads (26%) | catalogued as COSV64472153; called by muse, mutect2, varscan2
- HPCAL1 | c.231C>T p.D77= | Silent (SNP) | VAF 108/504 reads (21%) | catalogued as rs1324636807, COSV57144782; called by muse, mutect2, varscan2
- HYDIN | c.12363G>A p.Q4121= | Silent (SNP) | VAF 53/413 reads (13%) | catalogued as COSV101125040; called by muse, mutect2, varscan2
- IGHV3OR16-9 | c.12G>T p.L4= | Silent (SNP) | VAF 105/761 reads (14%) | catalogued as COSV100683808; called by muse, mutect2, varscan2
- MAP3K11 | c.2073C>T p.P691= | Silent (SNP) | VAF 110/595 reads (18%) | catalogued as COSV58419496; called by muse, mutect2, varscan2
- NDUFA11 | c.369C>T p.S123= | Silent (SNP) | VAF 79/509 reads (16%) | catalogued as COSV99398952; called by muse, mutect2, varscan2
- OPTN | c.507C>T p.N169= | Silent (SNP) | VAF 193/520 reads (37%) | catalogued as rs1564357558; called by muse, mutect2, varscan2
- RASGRF2 | c.1425G>A p.G475= | Silent (SNP) | VAF 110/312 reads (35%) | catalogued as rs775545658, COSV99428769; called by muse, mutect2, varscan2
- RERE | c.3120C>T p.V1040= | Silent (SNP) | VAF 78/383 reads (20%) | catalogued as COSV61936432; called by muse, mutect2, varscan2
- SLC25A23 | c.675C>T p.I225= | Silent (SNP) | VAF 67/420 reads (16%) | called by muse, mutect2, varscan2
- ST13 | c.1005C>T p.F335= | Silent (SNP) | VAF 114/316 reads (36%) | called by muse, mutect2, varscan2
- TCF4 | c.228T>C p.I76= | Silent (SNP) | VAF 25/167 reads (15%) | called by muse, mutect2, varscan2
- TMEM39B | c.675C>T p.P225= | Silent (SNP) | VAF 117/419 reads (28%) | called by muse, mutect2, varscan2
- TMTC1 | c.78G>T p.P26= | Silent (SNP) | VAF 124/492 reads (25%) | catalogued as rs975225996; called by muse, mutect2, varscan2
- TNFAIP8L3 | c.495C>T p.I165= | Silent (SNP) | VAF 106/421 reads (25%) | catalogued as COSV59528320; called by muse, mutect2, varscan2
- TTN | c.49815C>A p.A16605= (on ENST00000591111; = p.A9181= on NM_003319.4) | Silent (SNP) | VAF 141/431 reads (33%) | called by muse, mutect2, varscan2
- UBTD1 | c.576C>T p.F192= | Silent (SNP) | VAF 219/499 reads (44%) | called by muse, mutect2, varscan2
- VWF | c.7671C>T p.C2557= | Silent (SNP) | VAF 93/388 reads (24%) | called by muse, mutect2, varscan2
- ARHGEF3 | c.97-1221del | Intron (DEL) | VAF 33/261 reads (13%) | called by mutect2, pindel, varscan2
- TBCE | c.372-3551G>A | Intron (SNP) | VAF 41/237 reads (17%) | called by muse, mutect2, varscan2
- TGM5 | chr15:43268240 G>A | 5'Flank (SNP) | VAF 95/379 reads (25%) | called by muse, mutect2, varscan2
